Surgical pathology report (de-identified scan), TCGA case TCGA-B6-A0IE, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Duke, specimen TCGA-B6-A0IE-01A (Primary Tumor).

105-0-3

Carcinoma, lobule, NOS 8520/3

Site Code: breast, NOS C50.9 1/17/11 per

Patient:

Surgical Pathology: Final

Surg Path

CLINICAL HISTORY:

Inflammatory breast ca. Breast cancer.

GROSS EXAMINATION:

A. "Left breast biopsy," received fresh. A fragment of skin which is 3.3 cm long and 0.4 cm in diameter attached to underlying fibroadipose tissue which is 2.7 cm thick x 3.5 x 1 cm in greatest dimensions. The specimen has been previously partially sectioned revealing a poorly defined area of pink tissue measuring approximately 2.5 x 1.5 x 1 cm in greatest dimensions. This does not represent the true sides of the lesion. Portions of the tissue have been submitted for ER/PR evaluation. It is noted that this is a representative fragment of larger lesion and margins are not required for the specimen. Representative sections are submitted in Blocks A1 and A2.

DIAGNOSIS:

A. BREAST, LEFT, INCISIONAL BIOPSY:

POORLY DIFFERENTIATED CARCINOMA WITH EXTENSIVE VASCULAR INVASION.
IN SITU CARCINOMA IS NOT PRESENT.

NOTE: THE TUMOR HAS FEATURES OF LOBULAR CARCINOMA, BUT AN IN SITU COMPONENT IS NOT PRESENT.

Verified by: "

iHPAA Discrepancy		X

Source: NCI Genomic Data Commons file 5815bb0b-3b91-4317-904f-a94011b7ce03 (TCGA-B6-A0IE.DFCA9C6E-710E-4645-9CFC-A908AAD583F3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).